Gene-level copy-number profile of tumor specimen TCGA-NH-A8F8-01A from TCGA case TCGA-NH-A8F8, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 79.9 years (29,185 days).
Specimen TCGA-NH-A8F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.95964d58-2d3f-44b6-a2da-9ba9aa387410.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NH-A8F8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/589e8165-2a15-4587-b828-e2ea4559f978

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 15,378; copy number 2: 40,122; copy number 3: 3,356; copy number 5: 957.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NH-A8F8-01A-72D-A40O-01): tumor purity 0.7, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 957 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:111,896,814–112,333,664, 13 genes, copy number 5: UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28.
- chr9:122,120,082–122,789,895, 26 genes, copy number 5: MIR4478, NDUFA8, MORN5, LHX6, RBM18, MRRF, PTGS1, AL162424.1, AL359636.1, AL359636.2, OR1J1, OR1J2, OR1J4, OR1N1, OR1N2, OR1L8, OR1H1P, OR1Q1, OR1B1, OR1L1, OR1L3, TLK1P1, OR1L4, OR1L6, SKA2P1, OR5C1.
- chr20:28,563,850–64,313,132, 918 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,957. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
